Somatic mutation profile of cancer-model specimen HCM-BROD-0206-C25-85A (3D Organoid, passage 5; aliquot HCM-BROD-0206-C25-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0206-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 73.2 years (26,732 days).
Specimen HCM-BROD-0206-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12b602c8-7710-4d1b-8e23-b089c7517d8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0206-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0206-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b4f0246-b374-4f25-ab71-a190f478eda6

The open-access MAF lists 218 somatic variants for this specimen: 168 protein-altering or splice-affecting, 40 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 40, Intron 5, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, 3'Flank 2, Splice Site 1, In Frame Del 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 340/340 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1585dup p.Y529Lfs*26 | Frame Shift Ins (INS) | VAF 511/715 reads (71%) | catalogued as rs398123332; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 364/364 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 415/417 reads (100%) | catalogued as rs1567551821, COSV52710769, COSV52715098, COSV52760685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH3B2 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 314/713 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs556949146, COSV62427953; called by muse, varscan2
- ASPH | c.1034T>G p.L345R | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101064102; called by muse, mutect2, varscan2
- BARD1 | c.2001+1G>A p.X667_splice | Splice Site (SNP) | VAF 219/344 reads (64%) | catalogued as rs768490891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC1 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 157/323 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as rs771216854; called by muse, mutect2, varscan2
- C1orf94 | c.1631A>G p.Q544R (on ENST00000488417 / NM_001134734.2; = p.Q354R on NM_032884.5) | Missense Mutation (SNP) | VAF 234/474 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1409053045; called by muse, mutect2, varscan2
- CA10 | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 141/268 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53338972; called by muse, mutect2, varscan2
- CA11 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50033811; called by muse, mutect2
- CD1A | c.169T>C p.W57R | Missense Mutation (SNP) | VAF 54/804 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs967100894; called by muse, mutect2
- DIS3L2 | c.962A>T p.K321M | Missense Mutation (SNP) | VAF 141/430 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99805985; called by muse, mutect2, varscan2
- DNAH6 | c.11312T>G p.F3771C | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99408497; called by muse, mutect2
- DOCK2 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 157/470 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56963361, COSV56971995; called by muse, mutect2, varscan2
- FBLN2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 288/607 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369694803; called by muse, mutect2, varscan2
- FNDC1 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 548/548 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs538507376, COSV51931507; called by muse, mutect2, varscan2
- FOXH1 | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 316/1318 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs982305078; called by muse, mutect2, varscan2
- GLI3 | c.3115G>A p.A1039T | Missense Mutation (SNP) | VAF 314/936 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770430876, COSV67895478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEY2 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 719/719 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs1238653841; called by muse, mutect2, varscan2
- HMCN1 | c.13288C>T p.R4430C | Missense Mutation (SNP) | VAF 141/462 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141440732; called by muse, mutect2, varscan2
- IGDCC3 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 241/478 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.677); catalogued as rs1322383051; called by muse, mutect2, varscan2
- INPPL1 | c.3644_3646del p.E1215del | In Frame Del (DEL) | VAF 490/1075 reads (46%) | catalogued as rs1195604261; called by pindel, varscan2
- ISY1-RAB43 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.033); catalogued as rs750024487, COSV56441164; called by muse, mutect2, varscan2
- MLH3 | c.4292T>C p.L1431P (on ENST00000355774 / NM_001040108.2; = p.L1407P on NM_014381.3) | Missense Mutation (SNP) | VAF 171/296 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1313479174; called by muse, mutect2, varscan2
- MUC16 | c.15719A>C p.K5240T | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV67482693; called by muse, mutect2, varscan2
- NPHP1 | c.2047C>T p.R683W (on ENST00000393272 / NM_207181.4; = p.R684W on NM_000272.5) | Missense Mutation (SNP) | VAF 266/819 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141686332; called by muse, mutect2, varscan2
- OCLN | c.654A>C p.Q218H | Missense Mutation (SNP) | VAF 35/841 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1382120974; called by muse, mutect2
- OR2T34 | c.26A>C p.Q9P | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs147194614; called by muse, mutect2, varscan2
- OR4C3 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 234/968 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV60585924; called by muse, mutect2, varscan2
- OR52B2 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 110/549 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.346); catalogued as COSV101603966; called by muse, mutect2, varscan2
- OVCH1 | c.2957T>G p.L986R | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1298538596; called by muse, mutect2
- PAPOLB | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 240/720 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs1401691433, COSV68200319; called by muse, mutect2, varscan2
- PCDHA4 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 337/1044 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV100793391; called by muse, mutect2, varscan2
- PRB3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 203/422 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs758626674, COSV54391449; called by muse, mutect2, varscan2
- PTPN18 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 196/581 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs138592471; called by muse, mutect2, varscan2
- PTPRD | c.3748G>A p.V1250M | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs772029273, COSV100644112, COSV61928581; called by muse, mutect2
- RIMBP2 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 484/484 reads (100%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs769042353, COSV55483767; called by muse, mutect2, varscan2
- RNMT | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 156/510 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as rs746089526, COSV51085013; called by muse, mutect2, varscan2
- SLC6A9 | c.973G>A p.V325M (on ENST00000360584 / NM_201649.4; = p.V271M on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 212/423 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs200759556, COSV100746527, COSV100746583; called by muse, varscan2
- SLK | c.2393T>G p.F798C | Missense Mutation (SNP) | VAF 31/599 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59824565; called by muse, mutect2
- SQSTM1 | c.686C>G p.S229W | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99053998; called by muse, mutect2
- ST6GAL2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 26/790 reads (3%) | PolyPhen benign (0.005); catalogued as COSV64526997; called by muse, mutect2
- SYT10 | c.342A>C p.K114N | Missense Mutation (SNP) | VAF 215/425 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV57338918; called by muse, mutect2, varscan2
- THNSL1 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64479560; called by muse, mutect2, varscan2
- TLR4 | c.1316A>G p.E439G (on ENST00000355622 / NM_138554.5; = p.E399G on NM_003266.4) | Missense Mutation (SNP) | VAF 13/425 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV62922373, COSV62923773, COSV62924192; called by muse, mutect2
- UBR2 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 14/451 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100867463; called by muse, mutect2
- USP29 | c.1440A>C p.E480D | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54147292; called by muse, mutect2
- ZNF492 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV71761752, COSV71761974; called by muse, mutect2
- ZNF865 | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 332/1043 reads (32%) | SIFT tolerated, low confidence (0.26); catalogued as rs1484804816; called by muse, varscan2
- A2M | c.1219T>G p.F407V | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ABCC8 | c.4336T>G p.S1446A | Missense Mutation (SNP) | VAF 211/833 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ABCC9 | c.2284T>G p.L762V | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- AC011005.1 | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 54/611 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2
- ADAMTS12 | c.1229A>C p.E410A | Missense Mutation (SNP) | VAF 27/650 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRA3 | c.2897A>G p.E966G | Missense Mutation (SNP) | VAF 153/877 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ANKRD34C | c.709A>C p.S237R | Missense Mutation (SNP) | VAF 234/449 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AP2A2 | c.2755A>C p.T919P | Missense Mutation (SNP) | VAF 48/1016 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- APOB | c.4103A>C p.N1368T | Missense Mutation (SNP) | VAF 16/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP29 | c.3085A>C p.S1029R | Missense Mutation (SNP) | VAF 35/395 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); called by muse, mutect2
- BDP1 | c.7445A>C p.K2482T | Missense Mutation (SNP) | VAF 240/764 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- BICRA | c.1780G>C p.A594P | Missense Mutation (SNP) | VAF 286/1032 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- BPIFB4 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 287/1068 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C2CD2L | c.1304T>C p.L435P | Missense Mutation (SNP) | VAF 28/1113 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- CACNA1D | c.4490A>C p.K1497T (on ENST00000350061 / NM_001128840.3; = p.K1517T on NM_000720.4) | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CBY2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 24/830 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.749); called by muse, mutect2
- CCDC102A | c.16A>C p.S6R | Missense Mutation (SNP) | VAF 194/396 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CCT2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD14 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 92/993 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH23 | c.508T>C p.S170P | Missense Mutation (SNP) | VAF 284/805 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- CDK11B | c.1838A>C p.K613T | Missense Mutation (SNP) | VAF 144/468 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDKL3 | c.723A>C p.Q241H | Missense Mutation (SNP) | VAF 50/662 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CEBPG | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 210/889 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CILK1 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CNTD1 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CNTN2 | c.2437A>T p.R813W | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CNTNAP2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 37/679 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL7A1 | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 44/666 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CORIN | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 146/440 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPAMD8 | c.4142A>T p.K1381M (on ENST00000651564; = p.K1334M on NM_015692.5) | Missense Mutation (SNP) | VAF 15/431 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- CUL5 | c.273A>C p.K91N | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DBX1 | c.70A>C p.T24P | Missense Mutation (SNP) | VAF 86/1471 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- DCST2 | c.1189T>G p.L397V | Missense Mutation (SNP) | VAF 37/454 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- DIPK2A | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 318/463 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH17 | c.3692C>G p.P1231R | Missense Mutation (SNP) | VAF 155/571 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DNAJB13 | c.533A>C p.K178T | Missense Mutation (SNP) | VAF 30/892 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- DOT1L | c.3917T>C p.L1306P | Missense Mutation (SNP) | VAF 77/681 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYM | c.1204T>G p.L402V | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DZIP1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 833/835 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EGR3 | c.475T>G p.S159A | Missense Mutation (SNP) | VAF 60/616 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- EIF5A2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 110/700 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- FERMT3 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 40/1046 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FLT1 | c.3447A>C p.E1149D | Missense Mutation (SNP) | VAF 143/517 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FMO3 | c.664A>C p.S222R | Missense Mutation (SNP) | VAF 25/601 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.25); called by muse, mutect2
- GALNT17 | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 109/377 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GATAD2B | c.421A>T p.R141* | Nonsense Mutation (SNP) | VAF 44/760 reads (6%) | called by muse, mutect2
- GID4 | c.770T>G p.F257C | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GLRA1 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 191/557 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLS2 | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- GLUD2 | c.1594T>G p.L532V | Missense Mutation (SNP) | VAF 316/592 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GRK7 | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 40/1020 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRN | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 173/417 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GTPBP2 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- HCFC1R1 | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- HECA | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 29/639 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2
- HGH1 | c.803T>G p.V268G | Missense Mutation (SNP) | VAF 154/918 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- HOXA4 | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 186/653 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HPCA | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 151/350 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- HR | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 45/462 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.6823G>A p.A2275T | Missense Mutation (SNP) | VAF 86/491 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IQGAP3 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRAG1 | c.479A>C p.N160T | Missense Mutation (SNP) | VAF 264/1088 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRS1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 48/994 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ITGB3 | c.2286A>T p.R762S | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- KIF3B | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 36/780 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KMT2C | c.10636C>T p.Q3546* | Nonsense Mutation (SNP) | VAF 397/601 reads (66%) | called by muse, mutect2, varscan2
- KNTC1 | c.4241T>G p.L1414R | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LDLRAD1 | c.596A>C p.E199A | Missense Mutation (SNP) | VAF 29/441 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LMLN2 | c.1646T>G p.L549R | Missense Mutation (SNP) | VAF 182/395 reads (46%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- MALT1 | c.1159_1160del p.T387* | Frame Shift Del (DEL) | VAF 284/388 reads (73%) | called by mutect2, pindel, varscan2
- MAOB | c.271C>G p.H91D | Missense Mutation (SNP) | VAF 245/246 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1142A>T p.Y381F | Missense Mutation (SNP) | VAF 69/1270 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MNT | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 68/660 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- MRPL10 | c.71A>C p.Q24P | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- MTCL1 | c.1622A>C p.K541T (on ENST00000306329 / NM_001378206.1; = p.K181T on NM_015210.4) | Missense Mutation (SNP) | VAF 179/658 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NBPF11 | c.1469A>G p.D490G | Missense Mutation (SNP) | VAF 261/512 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NCAPH | c.816T>G p.S272R | Missense Mutation (SNP) | VAF 143/677 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NEB | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 167/512 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NFX1 | c.1960T>C p.S654P | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NPY2R | c.1100A>G p.K367R | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- OMA1 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 111/237 reads (47%) | called by muse, mutect2, varscan2
- OPN4 | c.1244A>C p.E415A | Missense Mutation (SNP) | VAF 177/624 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- OR10AG1 | c.802T>G p.F268V | Missense Mutation (SNP) | VAF 116/556 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- OTOG | c.6883T>A p.F2295I | Missense Mutation (SNP) | VAF 255/1196 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PAX1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 31/1132 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PBX1 | c.961A>C p.S321R | Missense Mutation (SNP) | VAF 132/543 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PCDH15 | c.4706A>C p.K1569T | Missense Mutation (SNP) | VAF 206/584 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PDE8B | c.1090G>C p.V364L | Missense Mutation (SNP) | VAF 175/550 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PDIA4 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 138/456 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZK1IP1 | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 17/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLEKHA4 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 28/1060 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- PLPPR4 | c.1945T>C p.W649R | Missense Mutation (SNP) | VAF 131/245 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPM1L | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 160/736 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTCHD4 | c.1138T>G p.F380V | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RAB44 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 278/566 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RNF43 | c.935G>T p.C312F | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTN2 | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 39/835 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- SLC2A7 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SPP1 | c.721A>G p.K241E (on ENST00000395080 / NM_001040058.2; = p.K227E on NM_000582.2) | Missense Mutation (SNP) | VAF 413/413 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSC4D | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 632/964 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- STOX1 | c.2350A>C p.S784R | Missense Mutation (SNP) | VAF 68/758 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2
- SULT1A2 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 490/512 reads (96%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TACC2 | c.1084T>G p.S362A | Missense Mutation (SNP) | VAF 30/1048 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- TMEM38A | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 230/478 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNPO1 | c.849A>C p.E283D | Missense Mutation (SNP) | VAF 31/517 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- TNS2 | c.3831_3855del p.S1277Rfs*5 (on ENST00000314250 / NM_170754.4; = p.S1287Rfs*5 on NM_015319.2) | Frame Shift Del (DEL) | VAF 54/581 reads (9%) | called by mutect2, pindel
- TTI1 | c.125A>C p.D42A | Missense Mutation (SNP) | VAF 221/687 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3239A>C p.E1080A | Missense Mutation (SNP) | VAF 151/506 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- USP26 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 15/508 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2
- WDR24 | c.1107_1110dup p.R371Afs*55 (on ENST00000248142; = p.R241Afs*55 on NM_032259.4) | Frame Shift Ins (INS) | VAF 408/452 reads (90%) | called by mutect2, pindel*, varscan2
- WRN | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); called by muse, mutect2
- Z82206.1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 222/470 reads (47%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- ZFYVE26 | c.4529A>T p.E1510V | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); called by muse, mutect2
- ZIM3 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 136/367 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZNF180 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 153/699 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF578 | c.1107A>C p.K369N | Missense Mutation (SNP) | VAF 161/573 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF624 | c.2401A>C p.I801L | Missense Mutation (SNP) | VAF 158/322 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF646 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 231/575 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ADGRL3 | c.3453C>T p.L1151= (on ENST00000506720 / NM_001322402.2; = p.L1083= on NM_015236.6) | Silent (SNP) | VAF 38/366 reads (10%) | catalogued as rs530568083; called by muse, mutect2, varscan2
- ARHGAP12 | c.1521C>T p.S507= | Silent (SNP) | VAF 145/278 reads (52%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.5220A>G p.G1740= | Silent (SNP) | VAF 216/444 reads (49%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1413T>G p.S471= | Silent (SNP) | VAF 26/740 reads (4%) | called by muse, mutect2
- CD2AP | c.489A>G p.K163= | Silent (SNP) | VAF 35/343 reads (10%) | called by muse, mutect2, varscan2
- CDC20B | c.226A>C p.R76= | Silent (SNP) | VAF 226/703 reads (32%) | catalogued as COSV57052783, COSV57054933; called by muse, mutect2, varscan2
- CFAP299 | c.414G>A p.T138= | Silent (SNP) | VAF 348/348 reads (100%) | catalogued as rs374347843; called by muse, mutect2, varscan2
- CRIP1 | c.27G>A p.K9= | Silent (SNP) | VAF 606/607 reads (100%) | catalogued as rs1204290801; called by muse, mutect2, varscan2
- CSMD3 | c.4693A>C p.R1565= (on ENST00000297405 / NM_001363185.1; = p.R1461= on NM_052900.3) | Silent (SNP) | VAF 185/532 reads (35%) | catalogued as COSV52091423; called by muse, mutect2, varscan2
- CYFIP2 | c.1594T>C p.L532= | Silent (SNP) | VAF 50/726 reads (7%) | catalogued as COSV59041025; called by muse, mutect2
- DHX38 | c.2880C>T p.I960= | Silent (SNP) | VAF 259/550 reads (47%) | catalogued as rs183625590; called by muse, mutect2, varscan2
- DPP9 | c.300G>A p.L100= (on ENST00000598800; = p.L129= on NM_139159.5) | Silent (SNP) | VAF 148/309 reads (48%) | catalogued as rs1314426182; called by muse, mutect2, varscan2
- FAM83C | c.1554A>G p.R518= | Silent (SNP) | VAF 359/955 reads (38%) | called by muse, mutect2, varscan2
- FOXP2 | c.2103C>T p.D701= | Silent (SNP) | VAF 138/496 reads (28%) | catalogued as rs559347815; ClinVar: likely benign; called by muse, mutect2, varscan2
- FTCD | c.597C>T p.I199= | Silent (SNP) | VAF 309/597 reads (52%) | catalogued as rs773170658, COSV52429183; called by muse, mutect2, varscan2
- GGCX | c.1260T>C p.T420= | Silent (SNP) | VAF 35/303 reads (12%) | catalogued as rs72940574; called by muse, mutect2, varscan2
- GPATCH4 | c.1110A>G p.R370= | Silent (SNP) | VAF 241/363 reads (66%) | called by muse, mutect2, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 281/602 reads (47%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- LMAN1 | c.1326C>T p.H442= | Silent (SNP) | VAF 298/298 reads (100%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1371C>T p.F457= | Silent (SNP) | VAF 174/394 reads (44%) | catalogued as rs571925919, COSV55938859; called by muse, mutect2, varscan2
- MUC17 | c.6219T>G p.T2073= | Silent (SNP) | VAF 36/672 reads (5%) | called by muse, mutect2
- MUCL3 | c.672T>G p.S224= | Silent (SNP) | VAF 358/1030 reads (35%) | called by muse, mutect2, varscan2
- MYH2 | c.3130T>C p.L1044= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- NCF4 | c.303C>T p.I101= | Silent (SNP) | VAF 268/533 reads (50%) | catalogued as rs746977479, COSV50620367; called by muse, mutect2, varscan2
- OR5M3 | c.483T>G p.T161= | Silent (SNP) | VAF 56/979 reads (6%) | called by muse, mutect2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 210/844 reads (25%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- PCDHB7 | c.1161C>T p.D387= | Silent (SNP) | VAF 197/661 reads (30%) | catalogued as rs781909345, COSV50755569; called by muse, mutect2, varscan2
- PCDHGB2 | c.1380C>T p.H460= | Silent (SNP) | VAF 502/751 reads (67%) | catalogued as COSV99549341; called by muse, mutect2, varscan2
- PCSK2 | c.573C>T p.S191= | Silent (SNP) | VAF 303/505 reads (60%) | called by muse, varscan2
- PKM | c.1089A>G p.G363= | Silent (SNP) | VAF 252/495 reads (51%) | called by muse, mutect2, varscan2
- PTPRS | c.138G>A p.S46= | Silent (SNP) | VAF 66/575 reads (11%) | catalogued as rs140383630, COSV53611869; called by muse, mutect2, varscan2
- RASGRP2 | c.1503C>T p.F501= | Silent (SNP) | VAF 83/1452 reads (6%) | catalogued as COSV62449716; called by muse, mutect2
- SCN10A | c.5286T>G p.S1762= | Silent (SNP) | VAF 248/471 reads (53%) | catalogued as rs750340252; called by muse, mutect2, varscan2
- SLC8A1 | c.2412C>T p.F804= | Silent (SNP) | VAF 306/593 reads (52%) | called by muse, mutect2, varscan2
- STARD9 | c.5376T>G p.A1792= | Silent (SNP) | VAF 232/457 reads (51%) | called by muse, mutect2, varscan2
- TAX1BP3 | c.207T>C p.A69= | Silent (SNP) | VAF 52/489 reads (11%) | catalogued as COSV50264956; called by muse, mutect2, varscan2
- TMPRSS15 | c.1125T>G p.S375= | Silent (SNP) | VAF 36/327 reads (11%) | called by muse, mutect2
- ZIK1 | c.1104A>G p.Q368= | Silent (SNP) | VAF 270/822 reads (33%) | called by muse, mutect2, varscan2
- ZNF569 | c.1953T>A p.L651= | Silent (SNP) | VAF 226/918 reads (25%) | called by muse, mutect2, varscan2
- ZNF721 | c.2163C>T p.S721= (on ENST00000338977; = p.S733= on NM_133474.4) | Silent (SNP) | VAF 234/888 reads (26%) | catalogued as COSV59097048; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52098438 C>T | 3'Flank (SNP) | VAF 40/452 reads (9%) | called by muse, mutect2
- BCAS4 | c.*37A>G | 3'UTR (SNP) | VAF 161/321 reads (50%) | called by muse, mutect2, varscan2
- DLG2 | c.1978+3726T>A | Intron (SNP) | VAF 159/667 reads (24%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+513A>G | Intron (SNP) | VAF 160/302 reads (53%) | catalogued as rs941698994; called by muse, mutect2, varscan2
- NACA | c.70+3261A>G | Intron (SNP) | VAF 54/620 reads (9%) | catalogued as rs773945190, COSV100771773; called by muse, mutect2
- PDE4A | chr19:10417823 T>C | 5'Flank (SNP) | VAF 54/593 reads (9%) | catalogued as rs928611563; called by muse, mutect2
- PLEKHJ1 | chr19:2230534 T>G | 3'Flank (SNP) | VAF 57/562 reads (10%) | called by muse, mutect2, varscan2
- PRKAG2 | c.115-28096A>G | Intron (SNP) | VAF 48/726 reads (7%) | called by muse, mutect2
- TTN | c.10360+5510T>G | Intron (SNP) | VAF 255/673 reads (38%) | called by muse, mutect2, varscan2
- ZSCAN2 | c.*628T>C | 3'UTR (SNP) | VAF 192/417 reads (46%) | catalogued as rs773556404; called by muse, mutect2, varscan2
